Somatic mutation profile of tumor specimen C3L-07057-01 (aliquot CPT0433270009) from CPTAC case C3L-07057, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 72.9 years (26,636 days).
Specimen C3L-07057-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e048c422-1365-4a19-9ef0-9cd7159d835f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07057-31 (Blood Derived Normal), aliquot CPT0433420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/347b2c1d-54dc-4872-9a76-3f72501773d4

The open-access MAF lists 594 somatic variants for this specimen: 429 protein-altering or splice-affecting, 152 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 394, Silent 152, Nonsense Mutation 25, Intron 8, Splice Site 4, 5'Flank 2, 3'UTR 2, Splice Region 2, Frame Shift Del 2, Translation Start Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1E | c.3275C>T p.T1092M | Missense Mutation (SNP) | VAF 17/365 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as rs1382064469, COSV62393664; ClinVar: likely pathogenic; called by muse, mutect2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 19/525 reads (4%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2
- SCARB2 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 18/406 reads (4%) | catalogued as rs886041078, CM143649, COSV53667794; ClinVar: pathogenic; called by muse, mutect2
- AATK | c.1402G>A p.V468M (on ENST00000326724 / NM_001080395.3; = p.V365M on NM_004920.2) | Missense Mutation (SNP) | VAF 22/648 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212575056; called by muse, mutect2
- ABO | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs781789696, COSV101505916; called by muse, mutect2
- AC068580.4 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1381606917, COSV52587715; called by muse, mutect2
- ACSF2 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1321082238; called by muse, mutect2
- ADRB3 | c.163A>G p.N55D | Missense Mutation (SNP) | VAF 37/689 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1305237262; called by muse, mutect2
- AGAP3 | c.1411G>A p.A471T (on ENST00000622464; = p.A507T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs376845402; called by muse, mutect2
- AJM1 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 32/634 reads (5%) | catalogued as rs1222994872; called by muse, mutect2
- AP2A2 | c.2611A>G p.I871V | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1340916538; called by muse, mutect2
- APCDD1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.474); catalogued as COSV62372446; called by muse, mutect2
- APOA5 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 30/602 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV57062910; called by muse, mutect2
- ARID1A | c.6125G>T p.S2042I | Missense Mutation (SNP) | VAF 22/545 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV61387209; called by muse, mutect2
- ARMC6 | c.355G>A p.D119N (on ENST00000392336; = p.D94N on NM_033415.4) | Missense Mutation (SNP) | VAF 19/441 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1269809775, COSV54184486; called by muse, mutect2
- ART1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 12/317 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1476619791; called by muse, mutect2
- ATP2B1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1161061134, COSV99665878; called by muse, mutect2
- BAHCC1 | c.4240C>T p.R1414C | Missense Mutation (SNP) | VAF 18/544 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782558549; called by muse, mutect2
- BAZ2A | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1394669070; called by muse, mutect2
- BRINP1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 31/561 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.055); catalogued as COSV56294619; called by muse, mutect2
- C16orf89 | c.302C>G p.A101G | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.169); catalogued as rs1455916314; called by muse, mutect2
- C6orf136 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.674); catalogued as COSV99528070; called by muse, mutect2
- CASKIN1 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 42/770 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs746712782; called by muse, mutect2
- CASP3 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 22/242 reads (9%) | catalogued as rs757302190, COSV57725725; called by muse, mutect2
- CCR7 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 27/467 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs760394768, COSV55850298; called by muse, mutect2
- CD4 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 19/474 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs150742570, COSV50590655; called by muse, mutect2
- CDC42EP1 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 35/575 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV50757116; called by muse, mutect2
- CDC5L | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 21/507 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1006568146, COSV65176002; called by muse, mutect2
- CDH12 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66416952; called by muse, mutect2
- CDH22 | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 25/592 reads (4%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.516); catalogued as COSV100952691; called by muse, mutect2
- CHERP | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 28/634 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52225720; called by muse, mutect2
- CNOT3 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 21/504 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs375507060; called by muse, mutect2
- CNTFR | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 36/520 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as rs760145709, COSV63634026; called by muse, mutect2
- COL7A1 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs868465415, COSV60391056; called by muse, mutect2
- CRACD | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 25/750 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.182); catalogued as rs1321187302; called by muse, mutect2
- CRIM1 | c.2549C>T p.S850L | Missense Mutation (SNP) | VAF 24/568 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1273757527, COSV54858950; called by muse, mutect2
- CUX1 | c.1108G>A p.E370K (on ENST00000292535 / NM_181552.4; = p.E381K on NM_001913.5) | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.16); catalogued as rs782320090, COSV52910563; called by muse, mutect2
- CXCR2 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1273183086; called by muse, mutect2
- CYFIP2 | c.2544G>A p.M848I (on ENST00000616178 / NM_001291722.2; = p.M823I on NM_014376.4) | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.284); catalogued as rs1413796917; called by muse, mutect2
- D2HGDH | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs1374662899; called by muse, mutect2
- DENND1B | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1429830003, COSV52469091; called by muse, mutect2
- DEPDC1B | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1432847616, COSV54012136; called by muse, mutect2
- DGKD | c.3625G>A p.A1209T (on ENST00000264057 / NM_152879.3; = p.A1165T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs938325613, COSV51034100; called by muse, mutect2
- DNAH10 | c.6064G>A p.D2022N (on ENST00000409039; = p.D1961N on NM_207437.3) | Missense Mutation (SNP) | VAF 29/611 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752796098, COSV101292409; called by muse, mutect2
- DNAJA2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1251966743, COSV57694475; called by muse, mutect2
- DNAJC7 | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57269337; called by muse, mutect2
- DPP9 | c.2068G>A p.E690K (on ENST00000598800; = p.E719K on NM_139159.5) | Missense Mutation (SNP) | VAF 23/375 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1357247710; called by muse, mutect2
- DTX1 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 32/669 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1489654894, COSV99986571; called by muse, mutect2
- DUSP22 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 31/949 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV60527410; called by muse, mutect2
- EDC4 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.537); catalogued as rs1214063850; called by muse, mutect2
- EGFL8 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 32/631 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.328); catalogued as rs759709000; called by muse, mutect2
- ELL | c.468G>A p.L156= | Splice Region (SNP) | VAF 14/328 reads (4%) | catalogued as COSV99443805; called by muse, mutect2
- ENPP7 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 27/595 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs782178230, COSV60385205; called by muse, mutect2
- EPPK1 | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 22/534 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.229); catalogued as rs1554661434; called by muse, mutect2
- ESR2 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 30/483 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs376023274; called by muse, mutect2
- EVC | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs1328905724; called by muse, mutect2
- FAM135A | c.4418A>G p.Y1473C (on ENST00000370479 / NM_001351599.1; = p.Y1260C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52056545; called by muse, mutect2
- FAM71F1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 22/557 reads (4%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.365); catalogued as COSV59373626; called by muse, mutect2
- FAN1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs755260620; called by muse, mutect2
- FBXL22 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 22/709 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62216455; called by muse, mutect2
- FBXO42 | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 15/516 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs904540801; called by muse, mutect2
- FBXO6 | c.772A>G p.S258G | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs937645493; called by muse, mutect2
- FIZ1 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 26/700 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV55609616; called by muse, mutect2
- FOXD2 | c.632T>C p.F211S | Missense Mutation (SNP) | VAF 36/792 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58303653; called by muse, mutect2
- FOXP3 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs782188307; called by muse, mutect2
- GAS6 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1566356890; called by muse, mutect2
- GATAD2B | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100897853; called by muse, mutect2
- GPR25 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 19/602 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1408948831; called by muse, mutect2
- GPR37L1 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 46/548 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs748607219; called by muse, mutect2
- GPR50 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 25/318 reads (8%) | catalogued as COSV54437559; called by muse, mutect2
- GRIK1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 23/392 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV58716574; called by muse, mutect2
- HAPLN4 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 38/688 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99364046; called by muse, mutect2
- HHIPL1 | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 42/721 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs755061217, COSV58090058; called by muse, mutect2
- IGFN1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs553115448; called by muse, mutect2
- IGSF9B | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 32/629 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1464598002, COSV58065179; called by muse, mutect2
- INPP5D | c.875G>A p.R292Q (on ENST00000445964 / NM_001017915.3; = p.R291Q on NM_005541.5) | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.774); catalogued as rs573550640; called by muse, mutect2
- INPP5D | c.1342G>A p.V448M (on ENST00000445964 / NM_001017915.3; = p.V447M on NM_005541.5) | Missense Mutation (SNP) | VAF 20/588 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64035367; called by muse, mutect2
- INVS | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 18/506 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1351418236; ClinVar: uncertain significance; called by muse, mutect2
- IRF6 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65420443; called by muse, mutect2
- ISX | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs536678640, COSV58085863; called by muse, mutect2
- ITGAX | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as COSV51651865; called by muse, mutect2
- JADE1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99886031; called by muse, mutect2
- KCNK2 | c.496C>T p.R166C (on ENST00000444842 / NM_001017425.3; = p.R151C on NM_014217.4) | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs576428312, COSV67203905; called by muse, mutect2
- KDM4F | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 20/504 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as rs539012892; called by muse, mutect2
- KIAA1549 | c.5702G>A p.R1901Q (on ENST00000422774 / NM_001164665.2; = p.R1885Q on NM_020910.3) | Missense Mutation (SNP) | VAF 24/748 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs1218121780; called by muse, mutect2
- KIF26B | c.6242C>T p.T2081M | Missense Mutation (SNP) | VAF 40/595 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771957676; called by muse, mutect2
- KLHL6 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 24/585 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.041); catalogued as COSV58067835; called by muse, mutect2
- KLK10 | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 20/470 reads (4%) | catalogued as COSV100011317; called by muse, mutect2
- KMT2C | c.14089A>G p.M4697V | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as rs1318648409; called by muse, mutect2
- KREMEN2 | c.1325C>T p.A442V (on ENST00000303746 / NM_172229.3; = p.R416W on NM_024507.4) | Missense Mutation (SNP) | VAF 23/596 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV99233970; called by muse, mutect2
- KRT33A | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 24/565 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as rs747309936, COSV50365546; called by muse, mutect2
- LCE3B | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.485); catalogued as rs764350326, COSV59500779; called by muse, mutect2
- LGI4 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 17/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs887920156; called by muse, mutect2
- LONP1 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 25/520 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs982440168; called by muse, mutect2
- LRCH2 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs782261827; called by muse, mutect2
- LRFN1 | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 22/529 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV50437261; called by muse, mutect2
- LRRC8A | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99396740; called by muse, mutect2
- LSM1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 20/347 reads (6%) | catalogued as rs961755643; called by muse, mutect2
- LTBP2 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 22/487 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436865679, COSV56209982; called by muse, mutect2
- MECP2 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782467549; ClinVar: uncertain significance; called by muse, mutect2
- MPO | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1162500182; called by muse, mutect2
- MYO9B | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68278265; called by muse, mutect2
- MYO9B | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 23/525 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as rs1237355706; called by muse, mutect2
- NAA16 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1411022224; called by muse, mutect2
- NOTCH3 | c.905G>A p.C302Y | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54644842; called by muse, mutect2
- NPAS3 | c.1576C>T p.R526C (on ENST00000356141 / NM_001164749.2; = p.R494C on NM_022123.3) | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV60839070; called by muse, mutect2
- NPDC1 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 32/757 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1265403187; called by muse, mutect2
- NRXN3 | c.1859G>T p.S620I (on ENST00000335750 / NM_001330195.2; = p.S247I on NM_004796.6) | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100207529; called by muse, mutect2
- NSUN5 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 28/581 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53091855; called by muse, mutect2
- NUP155 | c.3196C>T p.R1066* (on ENST00000231498 / NM_153485.3; = p.R1007* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 14/318 reads (4%) | catalogued as COSV51528924; called by muse, mutect2
- NUP88 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 27/461 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs1005203542; called by muse, mutect2
- OR5A2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 21/425 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV57391534; called by muse, mutect2
- OSBPL11 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404388812, COSV56174786; called by muse, mutect2
- PAG1 | c.1082C>G p.T361S | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.13); catalogued as rs1164214881; called by muse, mutect2
- PCDHA12 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 18/700 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.284); catalogued as rs543806401, COSV56503478; called by muse, mutect2
- PCDHA2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 38/852 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65366566; called by muse, mutect2
- PCDHAC2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 19/518 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs1554229569; called by muse, mutect2
- PCDHB1 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs543900178; called by muse, mutect2
- PCDHB12 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 28/874 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as COSV99507056; called by muse, mutect2
- PCYT1B | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63265076; called by muse, mutect2
- PDCD11 | c.2652G>T p.Q884H | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as COSV100874366; called by muse, mutect2
- PDE9A | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196221237; called by muse, mutect2
- PDZD7 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 14/423 reads (3%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.922); catalogued as rs1052665117; ClinVar: uncertain significance; called by muse, mutect2
- PEG3 | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55624092, COSV55628749; called by muse, mutect2
- PES1 | c.1742A>C p.K581T | Missense Mutation (SNP) | VAF 41/431 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1244316403; called by muse, mutect2
- PLPPR3 | c.1060G>A p.V354M (on ENST00000520876 / NM_001270366.2; = p.V382M on NM_024888.2) | Missense Mutation (SNP) | VAF 36/668 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100608599; called by muse, mutect2
- PLXNB3 | c.1982G>A p.G661D | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as rs1270448175; called by muse, mutect2
- PNN | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 19/416 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as rs1411042636; called by muse, mutect2
- PPFIA4 | c.3460G>T p.G1154W (on ENST00000447715; = p.G1155W on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/522 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1406746425; called by muse, mutect2, varscan2
- PRMT5 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs996790023; called by muse, mutect2
- PTPRS | c.5534C>T p.P1845L | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257575436, COSV53617407; called by muse, mutect2
- PURA | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.81); catalogued as COSV58762312; called by muse, mutect2
- PXDN | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 21/643 reads (3%) | catalogued as rs1316655042, COSV99413112; called by muse, mutect2
- PXDNL | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 27/554 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs936865843, COSV62476590; called by muse, mutect2
- PXMP4 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54133873; called by muse, mutect2
- QSOX1 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 19/429 reads (4%) | catalogued as rs1262858843; called by muse, mutect2
- RAP1GAP | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 29/529 reads (5%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.942); catalogued as COSV51571492; called by muse, mutect2
- RASD1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as rs1314198672; called by muse, mutect2
- RET | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1210452561, COSV100393927; called by muse, mutect2
- RIMS2 | c.3146G>A p.R1049H (on ENST00000666250 / NM_001348490.2; = p.R857H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs995050197, COSV51669002; called by muse, mutect2
- RNF40 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 19/423 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61215136; called by muse, mutect2
- RRBP1 | c.2537G>A p.R846Q (on ENST00000377813 / NM_001365613.2; = p.R413Q on NM_004587.3) | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.411); catalogued as rs1470789254, COSV99054346; called by muse, mutect2
- SALL3 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 29/730 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs755761587; called by muse, mutect2
- SAP25 | c.340C>T p.P114S (on ENST00000538735; = p.P212S on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/504 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1246970044; called by muse, mutect2
- SCARB1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1195783332, COSV55551963; called by muse, mutect2
- SCN8A | c.5459G>A p.R1820Q | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs919754724, COSV61980357; called by muse, mutect2
- SCRIB | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 31/479 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs779811140, COSV100253340; called by muse, mutect2
- SDC2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.207); catalogued as rs200028820; called by muse, mutect2
- SEMA5A | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 17/502 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101228749; called by muse, mutect2
- SEPTIN10 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs777524713, COSV61780774; called by muse, mutect2
- SERPING1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 17/521 reads (3%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1010623673; called by muse, mutect2
- SIPA1 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 21/583 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1296866949; called by muse, mutect2
- SKAP2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1025140851, COSV61725796; called by muse, mutect2
- SLC29A2 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as rs776926721; called by muse, mutect2
- SLC2A11 | c.937G>A p.A313T (on ENST00000345044 / NM_001024938.4; = p.A320T on NM_030807.5) | Missense Mutation (SNP) | VAF 19/487 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs749380110; called by muse, mutect2
- SLC51A | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs1197255768, COSV99580365; called by muse, mutect2
- SLC9A7 | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.094); catalogued as rs1556295137; called by muse, mutect2
- SLITRK5 | c.1907C>A p.A636D | Missense Mutation (SNP) | VAF 34/628 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV61524604; called by muse, mutect2
- SMARCA2 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 21/511 reads (4%) | catalogued as rs1310373882; called by muse, mutect2
- SMARCC2 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57215836; called by muse, mutect2
- SNTG1 | c.609G>C p.W203C | Missense Mutation (SNP) | VAF 17/420 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52426237; called by muse, mutect2
- SNX29 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 21/470 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100030459; called by muse, mutect2
- SORCS3 | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV63802949; called by muse, mutect2
- SP100 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 33/457 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs200000871; called by muse, mutect2
- SP8 | c.958C>T p.R320C (on ENST00000361443 / NM_198956.4; = p.R338C on NM_182700.6) | Missense Mutation (SNP) | VAF 38/650 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1205287201; called by muse, mutect2
- SPON1 | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 25/548 reads (5%) | catalogued as COSV59957477; called by muse, mutect2
- SSTR5 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs1025100150, COSV53513105; called by muse, mutect2
- SUPT6H | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV58925777, COSV58927562; called by muse, mutect2
- SYTL3 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs1404510983; called by muse, mutect2
- TBC1D4 | c.2423T>C p.L808P | Missense Mutation (SNP) | VAF 21/377 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV66487541; called by muse, mutect2
- TBXA2R | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 41/694 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1423803534; called by muse, mutect2
- TERF2 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs775609799; called by muse, mutect2
- TFAP2B | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 17/330 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs939682057, COSV53829960; called by muse, mutect2
- TIE1 | c.3277C>T p.R1093C | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs948719231; called by muse, mutect2
- TLR5 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs769787865, COSV60558000; called by muse, mutect2
- TNS3 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs958026760, COSV60786219, COSV60790280; called by muse, mutect2
- TNXB | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 29/546 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1419658200, COSV64475369; called by muse, mutect2
- TOLLIP | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1406340776; called by muse, mutect2
- TRRAP | c.5869G>A p.V1957I (on ENST00000359863 / NM_001244580.1; = p.V1939I on NM_003496.3) | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs1288936188; called by muse, mutect2
- TRRAP | c.8089G>T p.G2697W (on ENST00000359863 / NM_001244580.1; = p.G2679W on NM_003496.3) | Missense Mutation (SNP) | VAF 31/549 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722492; called by muse, mutect2
- TTC8 | c.1043T>C p.I348T (on ENST00000338104 / NM_001288781.1; = p.I332T on NM_144596.4) | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV57626155; called by muse, mutect2
- TTPAL | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 36/552 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52829498; called by muse, mutect2
- UBA1 | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1556792891, COSV104411504; called by muse, mutect2, varscan2
- UPF1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 22/493 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1353979976; called by muse, mutect2
- USH2A | c.3901G>C p.G1301R | Missense Mutation (SNP) | VAF 42/523 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV56392551; called by muse, mutect2
- USP7 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 20/353 reads (6%) | catalogued as COSV61216252; called by muse, mutect2
- VPS13D | c.4169G>A p.R1390Q | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as rs555254469; called by muse, mutect2
- WDR81 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 21/670 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as rs562896991; called by muse, mutect2
- WTIP | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 31/492 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1465584190; called by muse, mutect2
- ZBTB16 | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100251911, COSV60090006, COSV60099514; called by muse, mutect2
- ZBTB7C | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59690148; called by muse, mutect2
- ZDHHC5 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1443715338; called by muse, mutect2
- ZNF839 | c.1393C>T p.R465* (on ENST00000558850 / NM_001267827.1; = p.R581* on NM_018335.5) | Nonsense Mutation (SNP) | VAF 28/439 reads (6%) | catalogued as rs757678865; called by muse, mutect2
- ABCA8 | c.4513T>C p.Y1505H | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2
- ABCF1 | c.1594A>G p.N532D (on ENST00000326195 / NM_001025091.2; = p.N494D on NM_001090.3) | Missense Mutation (SNP) | VAF 15/397 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2
- ACAN | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 23/618 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACD | c.1264A>G p.T422A (on ENST00000620338; = p.T333A on NM_022914.3) | Missense Mutation (SNP) | VAF 39/677 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ACTR8 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 22/572 reads (4%) | called by muse, mutect2
- ADCY1 | c.146T>A p.F49Y | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.958); called by muse, mutect2
- ADGRB1 | c.4654C>G p.Q1552E | Missense Mutation (SNP) | VAF 27/584 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- AHNAK | c.5974C>T p.P1992S | Missense Mutation (SNP) | VAF 34/670 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AKAP4 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- AKAP6 | c.6724T>G p.L2242V | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2
- ALPK3 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 26/668 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.4776T>A p.D1592E | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5807C>A p.T1936N | Missense Mutation (SNP) | VAF 28/512 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.328); called by muse, mutect2
- ANKRD63 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 19/563 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); called by muse, mutect2
- APOBEC1 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 15/283 reads (5%) | called by muse, mutect2
- ARFGEF3 | c.5731C>A p.L1911M | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ARHGAP21 | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- ARHGEF40 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 36/568 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- ASB18 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 21/488 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); called by muse, mutect2
- ASF1B | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 23/503 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ATP10A | c.3028C>T p.Q1010* | Nonsense Mutation (SNP) | VAF 20/474 reads (4%) | called by muse, mutect2
- ATP6V0A1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATXN1L | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.041); called by muse, mutect2
- ATXN7L1 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by muse, mutect2
- BCLAF3 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.23); called by muse, mutect2
- BHMG1 | c.1013-1G>A p.X338_splice | Splice Site (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- BMP6 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- BNC2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 19/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BRINP1 | c.1822T>A p.W608R | Missense Mutation (SNP) | VAF 14/392 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- BRPF1 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.751); called by muse, mutect2
- BTBD18 | c.1838T>C p.V613A | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- BTBD8 | c.3763G>A p.A1255T (on ENST00000636805 / NM_001376131.1; = p.A742T on NM_015237.4) | Missense Mutation (SNP) | VAF 19/406 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.906); called by muse, mutect2
- C15orf62 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- C1orf174 | c.453A>C p.E151D | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); called by muse, mutect2
- C4orf33 | c.94A>G p.M32V | Missense Mutation (SNP) | VAF 23/558 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.231); called by muse, mutect2
- C9 | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2
- CASKIN1 | c.1685T>C p.L562S | Missense Mutation (SNP) | VAF 13/387 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CASS4 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC168 | c.19504G>A p.V6502I | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2
- CCDC17 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 23/593 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- CCDC57 | c.1107A>C p.Q369H | Missense Mutation (SNP) | VAF 25/407 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CCDC91 | c.31-1G>T p.X11_splice | Splice Site (SNP) | VAF 13/275 reads (5%) | called by muse, mutect2
- CCM2 | c.1295T>A p.I432N | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- CDK4 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2
- CELF6 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 18/563 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2
- CEP192 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- CHRNA2 | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 27/588 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHRNE | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CIC | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 34/706 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CLSTN2 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CMIP | c.1879C>T p.R627W (on ENST00000537098 / NM_198390.2; = p.R533W on NM_030629.3) | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); called by muse, mutect2
- CNKSR2 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CNOT2 | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COG1 | c.2172G>T p.E724D | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL22A1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 37/672 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- CPNE8 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.176); called by muse, mutect2
- CPSF1 | c.2092C>A p.L698M | Missense Mutation (SNP) | VAF 17/457 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.546); called by muse, mutect2
- CSMD1 | c.6320G>A p.G2107E (on ENST00000520002; = p.G2106E on NM_033225.6) | Missense Mutation (SNP) | VAF 31/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DBH | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2
- DCLK1 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.804); called by muse, mutect2
- DEAF1 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- DIP2B | c.3313A>G p.T1105A | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2
- DYSF | c.3844-1G>A p.X1282_splice | Splice Site (SNP) | VAF 19/453 reads (4%) | called by muse, mutect2
- E2F2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 20/590 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); called by muse, mutect2
- EBLN1 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 14/371 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2
- EDARADD | c.638G>T p.R213M (on ENST00000334232 / NM_145861.4; = p.R203M on NM_080738.4) | Missense Mutation (SNP) | VAF 17/405 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2
- EEF1A2 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, mutect2
- EID3 | c.980T>G p.M327R | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- EIF6 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2
- EMILIN1 | c.3016C>A p.L1006M | Missense Mutation (SNP) | VAF 19/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EMP3 | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 19/440 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.368); called by muse, mutect2
- ENAM | c.3080G>A p.G1027D | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.061); called by muse, mutect2
- ERBIN | c.1133A>T p.N378I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESPNL | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 17/458 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- F13B | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.253); called by muse, mutect2
- FAM189A2 | c.304T>G p.L102V | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAT4 | c.9965T>A p.V3322E | Missense Mutation (SNP) | VAF 23/495 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- FEN1 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 30/455 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- FIGN | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 21/490 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); called by muse, mutect2
- FKBP15 | c.2794C>T p.Q932* | Nonsense Mutation (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- FKRP | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- FLNC | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- FLRT3 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FREM2 | c.6116A>G p.K2039R | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- FRMPD2 | c.2104T>A p.S702T | Missense Mutation (SNP) | VAF 19/456 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2
- FRMPD4 | c.486T>A p.F162L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); called by muse, mutect2
- FZD5 | c.1636A>G p.K546E | Missense Mutation (SNP) | VAF 22/551 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.055); called by muse, mutect2
- GABPB1 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2
- GABRB1 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- GAL3ST3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2
- GARNL3 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2
- GFOD1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 25/617 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- GGN | c.1949A>G p.H650R | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2
- GKN2 | c.432A>T p.K144N | Missense Mutation (SNP) | VAF 21/567 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2
- GOLM1 | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 28/453 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- GPC4 | c.1288del p.S430Afs*7 | Frame Shift Del (DEL) | VAF 15/140 reads (11%) | called by mutect2, pindel, varscan2
- GPR135 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.01); called by muse, mutect2
- GSC | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 36/572 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2
- GTF2IRD1 | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- HAPLN4 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.055); called by muse, mutect2
- HDAC11 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 27/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HELB | c.1109T>C p.L370P | Missense Mutation (SNP) | VAF 20/537 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HERC6 | c.2287A>G p.M763V | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2
- HHATL | c.1195T>C p.F399L | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.167); called by muse, mutect2
- HIPK2 | c.1617A>G p.T539= | Splice Region (SNP) | VAF 14/297 reads (5%) | called by muse, mutect2
- HMCES | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- HNRNPDL | c.672A>C p.K224N | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); called by muse, mutect2
- HNRNPUL1 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 27/461 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGSF22 | c.1811T>C p.I604T | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.196); called by muse, mutect2
- IL6R | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IRF2BPL | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- ITIH6 | c.3563A>T p.E1188V | Missense Mutation (SNP) | VAF 29/420 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.36); called by muse, mutect2
- ITM2C | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, mutect2
- KCNK15 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- KLHL32 | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2
- KNTC1 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- KRTAP12-2 | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 15/508 reads (3%) | called by muse, mutect2
- LAMA5 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- LATS2 | c.2087T>C p.M696T | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.475); called by muse, mutect2
- LEPR | c.3277C>A p.L1093I | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2
- LIN7C | c.349A>T p.I117F | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LOXL2 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- LRFN1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 28/655 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRK1 | c.5396C>G p.A1799G | Missense Mutation (SNP) | VAF 18/650 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- MAGEL2 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 38/938 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.228); called by muse, mutect2
- MAPK8IP2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MN1 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 67/714 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2
- MON2 | c.3451C>T p.Q1151* | Nonsense Mutation (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- MPP2 | c.646C>T p.P216S (on ENST00000461854 / NM_001278372.2; = p.P192S on NM_005374.5) | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.044); called by muse, mutect2
- MROH2A | c.3819G>T p.W1273C | Missense Mutation (SNP) | VAF 29/496 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC2 | c.1652C>G p.A551G | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- MUC2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 26/493 reads (5%) | SIFT tolerated, low confidence (0.71); called by muse, mutect2
- MYH13 | c.4715T>C p.V1572A | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.142); called by muse, mutect2
- MYH4 | c.3400G>A p.A1134T | Missense Mutation (SNP) | VAF 23/570 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- MYO7B | c.3420C>A p.C1140* | Nonsense Mutation (SNP) | VAF 16/315 reads (5%) | called by muse, mutect2
- NAV2 | c.6643A>G p.N2215D (on ENST00000396087 / NM_001244963.2; = p.N2156D on NM_145117.5) | Missense Mutation (SNP) | VAF 21/412 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.444); called by muse, mutect2
- NCSTN | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 11/375 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- NES | c.2222A>G p.H741R | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- NPR2 | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- NR4A3 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2
- NRG3 | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2
- NRSN2 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- NUFIP2 | c.844T>C p.Y282H | Missense Mutation (SNP) | VAF 17/479 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); called by muse, mutect2
- OR6C6 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2
- OR8J2 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ORC2 | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- PAIP2B | c.16A>G p.M6V | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PANX3 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 25/504 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2
- PCDH17 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 20/586 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA9 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 37/906 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- PCDHGA10 | c.2212G>T p.G738C | Missense Mutation (SNP) | VAF 46/742 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- PCDHGA4 | c.1910A>G p.Y637C | Missense Mutation (SNP) | VAF 18/421 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PCSK4 | c.2250G>A p.W750* | Nonsense Mutation (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- PCSK5 | c.4591C>T p.H1531Y | Missense Mutation (SNP) | VAF 23/546 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- PGBD2 | c.673T>G p.F225V | Missense Mutation (SNP) | VAF 20/445 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHKG1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 14/381 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PKD1L1 | c.8299A>G p.T2767A | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- PLCG1 | c.3665C>T p.P1222L (on ENST00000373271 / NM_182811.2; = p.P1223L on NM_002660.3) | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PLXNB3 | c.4790C>T p.T1597I | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PM20D2 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 24/653 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- POLE | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PPP2R2A | c.1084T>C p.Y362H | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- PRADC1 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRDM10 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 42/566 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRICKLE4 | c.881C>A p.P294H (on ENST00000359201; = p.P334H on NM_013397.6) | Missense Mutation (SNP) | VAF 17/449 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- PRKCQ | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 22/540 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PROSER1 | c.2579A>G p.Q860R | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2
- PROX1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 21/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PZP | c.2578C>T p.Q860* | Nonsense Mutation (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- R3HDM1 | c.2905A>T p.K969* | Nonsense Mutation (SNP) | VAF 14/365 reads (4%) | called by muse, mutect2
- REXO5 | c.1778A>G p.E593G | Missense Mutation (SNP) | VAF 20/465 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); called by muse, mutect2
- RFX8 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.371); called by muse, mutect2
- RILP | c.968T>A p.I323N | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- RIPK4 | c.2326A>G p.I776V (on ENST00000352483; = p.I728V on NM_020639.3) | Missense Mutation (SNP) | VAF 19/496 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2
- RUFY4 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 17/347 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- SALL2 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 36/563 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- SAP18 | c.450G>A p.M150I (on ENST00000607003; = p.M169I on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2
- SCRN1 | c.809A>C p.E270A | Missense Mutation (SNP) | VAF 19/477 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- SDR39U1 | c.228del p.E77Rfs*2 | Frame Shift Del (DEL) | VAF 16/236 reads (7%) | called by mutect2, pindel
- SERINC4 | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 19/421 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- SGSM2 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 43/539 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- SH3PXD2A | c.632A>C p.E211A | Missense Mutation (SNP) | VAF 17/363 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.842); called by muse, mutect2
- SIDT2 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 25/567 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2
- SIX6 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC15A3 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC17A5 | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 21/460 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- SLC22A2 | c.1532T>C p.V511A | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2
- SLC27A4 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC35F3 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 22/584 reads (4%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.366); called by muse, mutect2
- SLC4A3 | c.3196G>A p.A1066T | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.122); called by muse, mutect2
- SLC8A1 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2
- SLC8A3 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNRNP200 | c.1671+1G>A p.X557_splice | Splice Site (SNP) | VAF 10/276 reads (4%) | called by muse, mutect2
- SOX5 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.161); called by muse, mutect2
- SOX9 | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2
- SPEM3 | c.3128C>A p.S1043Y | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2
- ST6GALNAC5 | c.857A>G p.H286R | Missense Mutation (SNP) | VAF 20/474 reads (4%) | PolyPhen probably damaging (0.978); called by muse, mutect2
- STIM1 | c.731T>A p.M244K | Missense Mutation (SNP) | VAF 19/399 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- STXBP1 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2
- SVEP1 | c.8845T>A p.C2949S | Missense Mutation (SNP) | VAF 17/529 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYTL1 | c.950G>A p.R317H (on ENST00000543823; = p.R305H on NM_032872.3) | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SYTL1 | c.1306C>T p.P436S (on ENST00000543823; = p.P424S on NM_032872.3) | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.538); called by muse, mutect2
- TAPBPL | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 17/431 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCEAL8 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 21/230 reads (9%) | called by muse, mutect2
- TCP10L2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.024); called by muse, mutect2
- TENM4 | c.6812A>G p.Y2271C | Missense Mutation (SNP) | VAF 25/512 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TEP1 | c.6913A>T p.I2305F | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.205); called by muse, mutect2
- TERT | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- TMC8 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/420 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); called by muse, mutect2
- TMEM131 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 17/516 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2
- TMEM266 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 27/588 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- TMEM270 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.31); called by muse, mutect2
- TMEM63A | c.353C>A p.T118N | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.673); called by muse, mutect2
- TNKS1BP1 | c.3260T>C p.V1087A | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TOR4A | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 26/645 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2
- TP53I13 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.809); called by muse, mutect2
- TRANK1 | c.8492G>A p.S2831N | Missense Mutation (SNP) | VAF 23/493 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- TRGV2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 14/538 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.604); called by muse, mutect2
- TRHR | c.944T>C p.I315T | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- TTN | c.89056G>A p.V29686I (on ENST00000591111; = p.V22262I on NM_003319.4) | Missense Mutation (SNP) | VAF 20/552 reads (4%) | PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.24580G>A p.A8194T (on ENST00000591111; = p.A7267T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/420 reads (4%) | PolyPhen possibly damaging (0.815); called by muse, mutect2
- TTYH3 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 41/542 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TUBA1C | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 30/573 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2
- UBR4 | c.14813G>T p.R4938I | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- UBXN6 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UCN2 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 24/592 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- UGT1A4 | c.347T>G p.I116S | Missense Mutation (SNP) | VAF 31/545 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- URB2 | c.4109T>C p.L1370P | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- USP20 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.435); called by muse, mutect2
- VCAN | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 22/614 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2
- VWA1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 21/470 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.058); called by muse, mutect2
- VWA8 | c.3347A>G p.D1116G | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ZKSCAN8 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.221); called by muse, mutect2
- ZNF583 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 25/448 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.243); called by muse, mutect2
- ZNF630 | c.1397A>G p.K466R | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ZNHIT6 | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.038); called by muse, mutect2
- ABCB6 | c.777A>G p.P259= | Silent (SNP) | VAF 18/504 reads (4%) | called by muse, mutect2
- ABLIM2 | c.132C>T p.H44= | Silent (SNP) | VAF 14/318 reads (4%) | catalogued as COSV56408672; called by muse, mutect2
- ACTL9 | c.939C>T p.V313= | Silent (SNP) | VAF 28/606 reads (5%) | called by muse, mutect2
- ADAD2 | c.249G>A p.A83= | Silent (SNP) | VAF 28/804 reads (3%) | catalogued as rs925798020, COSV51895868; called by muse, mutect2
- ADAMTS10 | c.1623G>A p.S541= | Silent (SNP) | VAF 24/598 reads (4%) | catalogued as COSV54353331; called by muse, mutect2
- ADAMTS20 | c.120C>T p.Y40= | Silent (SNP) | VAF 19/303 reads (6%) | catalogued as COSV67140216; called by muse, mutect2
- ADGRG5 | c.969C>T p.Y323= | Silent (SNP) | VAF 30/590 reads (5%) | catalogued as rs1427562117, COSV100446304; called by muse, mutect2
- ADPRHL1 | c.2802C>T p.G934= | Silent (SNP) | VAF 31/540 reads (6%) | catalogued as rs1451462575; called by muse, mutect2
- AL592490.1 | c.2283C>T p.G761= | Silent (SNP) | VAF 20/454 reads (4%) | called by muse, mutect2
- AMELY | c.228G>A p.L76= (on ENST00000383036 / NM_001364814.1; = p.L62= on NM_001143.1) | Silent (SNP) | VAF 19/258 reads (7%) | called by muse, mutect2
- ANKRD13A | c.270G>A p.V90= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as rs1361614876; called by muse, mutect2
- ANKRD34C | c.1161G>A p.G387= | Silent (SNP) | VAF 19/461 reads (4%) | called by muse, mutect2
- ANKRD53 | c.207G>A p.A69= | Silent (SNP) | VAF 18/480 reads (4%) | catalogued as rs1288778466; called by muse, mutect2
- APOA4 | c.276C>T p.A92= | Silent (SNP) | VAF 15/450 reads (3%) | called by muse, mutect2
- ASPM | c.9207A>G p.G3069= | Silent (SNP) | VAF 17/334 reads (5%) | catalogued as rs1200083862; called by muse, mutect2
- BAAT | c.1128G>A p.T376= | Silent (SNP) | VAF 28/721 reads (4%) | catalogued as rs202090808, COSV52291190; called by muse, mutect2
- BAG6 | c.2523A>G p.T841= (on ENST00000676571; = p.T794= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/543 reads (5%) | called by muse, mutect2
- BCOR | c.2682G>A p.L894= | Silent (SNP) | VAF 20/273 reads (7%) | called by muse, mutect2
- BRSK1 | c.1569G>A p.T523= | Silent (SNP) | VAF 36/563 reads (6%) | catalogued as rs543933798; called by muse, mutect2
- C9orf40 | c.372C>T p.D124= | Silent (SNP) | VAF 21/377 reads (6%) | called by muse, mutect2
- CAAP1 | c.792C>T p.S264= | Silent (SNP) | VAF 30/476 reads (6%) | called by muse, mutect2
- CAV3 | c.198T>G p.T66= | Silent (SNP) | VAF 19/476 reads (4%) | called by muse, mutect2
- CCDC168 | c.14505T>A p.S4835= | Silent (SNP) | VAF 17/458 reads (4%) | called by muse, mutect2
- CFAP43 | c.387C>A p.S129= | Silent (SNP) | VAF 17/284 reads (6%) | catalogued as COSV99530751; called by muse, mutect2
- CNOT1 | c.4245T>C p.I1415= | Silent (SNP) | VAF 19/476 reads (4%) | called by muse, mutect2
- CPE | c.234G>A p.T78= | Silent (SNP) | VAF 22/590 reads (4%) | catalogued as COSV68581445; called by muse, mutect2
- CUX1 | c.4401C>T p.G1467= | Silent (SNP) | VAF 19/515 reads (4%) | catalogued as COSV52912307; called by muse, mutect2
- DOLK | c.291G>A p.E97= | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- DRP2 | c.996T>C p.L332= | Silent (SNP) | VAF 21/245 reads (9%) | called by muse, mutect2
- EAPP | c.384A>G p.Q128= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- EHD4 | c.708C>T p.Y236= | Silent (SNP) | VAF 17/577 reads (3%) | catalogued as rs1396555891, COSV55005927; called by muse, mutect2
- ELFN1 | c.1332G>C p.R444= | Silent (SNP) | VAF 43/658 reads (7%) | catalogued as rs532829046; called by muse, mutect2
- ENDOD1 | c.1383C>T p.G461= | Silent (SNP) | VAF 30/499 reads (6%) | catalogued as rs1175530005; called by muse, mutect2
- EPN1 | c.238C>T p.L80= | Silent (SNP) | VAF 8/185 reads (4%) | catalogued as rs1302702535; called by muse, mutect2
- EPRS1 | c.3468G>A p.K1156= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- ERBB4 | c.780T>G p.T260= | Silent (SNP) | VAF 17/381 reads (4%) | called by muse, mutect2
- ESPN | c.2290C>T p.L764= | Silent (SNP) | VAF 16/412 reads (4%) | called by muse, mutect2
- ESRRA | c.1116T>C p.G372= | Silent (SNP) | VAF 33/873 reads (4%) | called by muse, mutect2
- EWSR1 | c.699G>A p.G233= | Silent (SNP) | VAF 18/420 reads (4%) | called by muse, mutect2
- FAM136A | c.6T>A p.A2= | Silent (SNP) | VAF 24/465 reads (5%) | called by muse, mutect2
- FAM229A | c.210C>T p.S70= | Silent (SNP) | VAF 38/594 reads (6%) | called by muse, mutect2
- FLNA | c.393C>T p.D131= | Silent (SNP) | VAF 10/209 reads (5%) | catalogued as rs782315270; ClinVar: likely benign; called by muse, mutect2
- FLVCR1 | c.1143A>G p.G381= | Silent (SNP) | VAF 27/381 reads (7%) | called by muse, mutect2
- FNBP1 | c.729A>G p.P243= | Silent (SNP) | VAF 42/488 reads (9%) | called by muse, mutect2
- FRMD4A | c.2481G>A p.Q827= | Silent (SNP) | VAF 25/540 reads (5%) | called by muse, mutect2
- FZD9 | c.708C>T p.A236= | Silent (SNP) | VAF 28/548 reads (5%) | called by muse, mutect2
- G2E3 | c.981A>G p.S327= | Silent (SNP) | VAF 9/203 reads (4%) | called by muse, mutect2
- GAPVD1 | c.3720G>A p.R1240= (on ENST00000394104; = p.R1249= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/466 reads (4%) | catalogued as rs1043879147, COSV52923309; called by muse, mutect2
- GPNMB | c.930C>T p.S310= | Silent (SNP) | VAF 26/462 reads (6%) | called by muse, mutect2
- GPR153 | c.393C>T p.V131= | Silent (SNP) | VAF 15/356 reads (4%) | called by muse, mutect2
- GPR25 | c.366G>A p.T122= | Silent (SNP) | VAF 68/641 reads (11%) | called by muse, mutect2
- GRIN2D | c.72C>T p.C24= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as rs1366392407; called by muse, mutect2
- GTF3C1 | c.6019C>T p.L2007= | Silent (SNP) | VAF 34/516 reads (7%) | catalogued as rs1191090307; called by muse, mutect2
- HDGFL2 | c.333C>T p.A111= | Silent (SNP) | VAF 24/479 reads (5%) | catalogued as rs1369649320; called by muse, mutect2
- IL16 | c.183G>A p.V61= | Silent (SNP) | VAF 17/506 reads (3%) | called by muse, mutect2
- ILVBL | c.225T>C p.G75= | Silent (SNP) | VAF 26/562 reads (5%) | called by muse, mutect2
- IRGC | c.222G>A p.L74= | Silent (SNP) | VAF 28/626 reads (4%) | called by muse, mutect2
- JAKMIP3 | c.774G>A p.R258= | Silent (SNP) | VAF 23/533 reads (4%) | called by muse, mutect2
- KCNA3 | c.285C>T p.A95= | Silent (SNP) | VAF 42/676 reads (6%) | called by muse, mutect2
- KCNB2 | c.78C>T p.D26= | Silent (SNP) | VAF 23/438 reads (5%) | called by muse, mutect2
- KCNS1 | c.639G>A p.P213= | Silent (SNP) | VAF 23/544 reads (4%) | called by muse, mutect2
- KDM2B | c.3426C>T p.S1142= | Silent (SNP) | VAF 17/346 reads (5%) | called by muse, mutect2
- KIAA0319L | c.1998C>T p.T666= | Silent (SNP) | VAF 18/430 reads (4%) | catalogued as COSV100357764; called by muse, mutect2
- L3MBTL1 | c.600G>A p.A200= (on ENST00000418998 / NM_001377303.1; = p.A110= on NM_015478.7) | Silent (SNP) | VAF 28/555 reads (5%) | catalogued as rs1027969529, COSV100917327, COSV64232199; called by muse, mutect2
- LAMB2 | c.2391T>G p.P797= | Silent (SNP) | VAF 17/494 reads (3%) | called by muse, mutect2
- LLGL2 | c.186A>G p.P62= | Silent (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- LRRC26 | c.108G>A p.G36= | Silent (SNP) | VAF 34/576 reads (6%) | catalogued as rs1426079120; called by muse, mutect2
- MAGEL2 | c.1617G>A p.A539= | Silent (SNP) | VAF 25/628 reads (4%) | catalogued as rs1179159616; called by muse, mutect2
- MAP3K7 | c.447C>A p.P149= | Silent (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- MAST3 | c.2658T>C p.G886= | Silent (SNP) | VAF 30/710 reads (4%) | catalogued as COSV53217975; called by muse, mutect2
- MGAT3 | c.1575G>A p.R525= | Silent (SNP) | VAF 30/484 reads (6%) | catalogued as rs1422012966; called by muse, mutect2
- MICAL3 | c.4905G>A p.A1635= | Silent (SNP) | VAF 40/691 reads (6%) | catalogued as rs770032936; called by muse, mutect2
- MIGA2 | c.225T>G p.V75= | Silent (SNP) | VAF 23/591 reads (4%) | called by muse, mutect2
- MTNR1B | c.135G>A p.A45= | Silent (SNP) | VAF 29/521 reads (6%) | catalogued as COSV99924998; called by muse, mutect2
- MUC6 | c.369G>A p.L123= | Silent (SNP) | VAF 15/396 reads (4%) | catalogued as rs910149822; called by muse, mutect2
- MYO18B | c.4629G>T p.L1543= | Silent (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- NBR1 | c.1764C>T p.C588= | Silent (SNP) | VAF 17/314 reads (5%) | catalogued as COSV57835730; called by muse, mutect2
- NELL2 | c.1833C>T p.H611= | Silent (SNP) | VAF 14/321 reads (4%) | catalogued as COSV100419027; called by muse, mutect2
- NFKB2 | c.1443G>A p.L481= | Silent (SNP) | VAF 18/458 reads (4%) | called by muse, mutect2
- NFKBIL1 | c.780C>T p.S260= | Silent (SNP) | VAF 26/931 reads (3%) | called by muse, mutect2
- NR0B1 | c.72C>T p.R24= | Silent (SNP) | VAF 25/262 reads (10%) | called by muse, mutect2
- NYX | c.390C>A p.T130= | Silent (SNP) | VAF 28/396 reads (7%) | called by muse, mutect2
- OLIG2 | c.807C>T p.A269= | Silent (SNP) | VAF 32/600 reads (5%) | called by muse, mutect2
- PCDH9 | c.3528G>A p.G1176= (on ENST00000377865 / NM_203487.3; = p.G1142= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/550 reads (5%) | called by muse, mutect2
- PCDHA12 | c.651C>T p.G217= | Silent (SNP) | VAF 24/453 reads (5%) | catalogued as rs782271666, COSV56484717; called by muse, mutect2
- PCDHB11 | c.306C>T p.C102= | Silent (SNP) | VAF 28/431 reads (6%) | catalogued as rs782501792, COSV53378801; called by muse, mutect2
- PCDHGA2 | c.2328G>A p.A776= | Silent (SNP) | VAF 23/646 reads (4%) | catalogued as COSV53945136; called by muse, mutect2
- PGS1 | c.1182C>T p.A394= | Silent (SNP) | VAF 32/462 reads (7%) | called by muse, mutect2
- PHIP | c.1428G>A p.P476= | Silent (SNP) | VAF 17/384 reads (4%) | catalogued as rs1341117287, COSV51502426; called by muse, mutect2
- PINK1 | c.879C>T p.V293= | Silent (SNP) | VAF 23/561 reads (4%) | catalogued as rs1242909775; called by muse, mutect2
- PLEC | c.8653C>T p.L2885= (on ENST00000322810 / NM_201380.4; = p.L2775= on NM_000445.5) | Silent (SNP) | VAF 25/502 reads (5%) | catalogued as rs782370389; called by muse, mutect2
- PLXNB3 | c.3576C>T p.R1192= | Silent (SNP) | VAF 16/340 reads (5%) | catalogued as rs782210956, COSV62798143; called by muse, mutect2
- POC1B-GALNT4 | c.1635T>C p.L545= | Silent (SNP) | VAF 28/449 reads (6%) | catalogued as COSV57967503; called by muse, mutect2
- POGZ | c.1569C>T p.N523= | Silent (SNP) | VAF 12/387 reads (3%) | catalogued as rs991557635; called by muse, mutect2
- PRDM11 | c.393T>G p.S131= (on ENST00000530656 / NM_001359633.1; = p.S97= on NM_001256695.1) | Silent (SNP) | VAF 29/542 reads (5%) | called by muse, mutect2
- PRKCQ | c.1111C>T p.L371= | Silent (SNP) | VAF 17/335 reads (5%) | catalogued as COSV54116267, COSV99578108; called by muse, mutect2
- PRKDC | c.4623G>A p.A1541= | Silent (SNP) | VAF 32/464 reads (7%) | catalogued as rs1272814002; called by muse, mutect2
- PRRC2A | c.1332T>C p.D444= | Silent (SNP) | VAF 22/609 reads (4%) | called by muse, mutect2
- PXDNL | c.2289G>A p.A763= | Silent (SNP) | VAF 36/596 reads (6%) | called by muse, mutect2
- RAD21L1 | c.957G>A p.A319= | Silent (SNP) | VAF 15/373 reads (4%) | catalogued as rs1364604836, COSV67881807; called by muse, mutect2
- RASGRP3 | c.1453C>T p.L485= (on ENST00000402538 / NM_001349975.2; = p.L484= on NM_015376.2 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 26/409 reads (6%) | called by muse, mutect2
- RNASE9 | c.366A>G p.P122= | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- RNPEP | c.159C>A p.G53= | Silent (SNP) | VAF 42/658 reads (6%) | catalogued as rs1314985098; called by muse, mutect2
- RSC1A1 | c.324T>C p.G108= | Silent (SNP) | VAF 38/503 reads (8%) | called by muse, mutect2
- SBNO2 | c.1218C>T p.D406= | Silent (SNP) | VAF 31/484 reads (6%) | called by muse, mutect2
- SCAF1 | c.1332C>T p.D444= | Silent (SNP) | VAF 35/583 reads (6%) | catalogued as rs1480036351; called by muse, mutect2
- SECISBP2 | c.156G>A p.P52= | Silent (SNP) | VAF 18/342 reads (5%) | catalogued as rs952957643, COSV100068881; called by muse, mutect2
- SHANK3 | c.2643C>T p.R881= | Silent (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- SIM2 | c.1044C>A p.S348= | Silent (SNP) | VAF 20/398 reads (5%) | catalogued as COSV51769016; called by muse, mutect2
- SIX3 | c.939C>T p.R313= | Silent (SNP) | VAF 26/560 reads (5%) | catalogued as COSV53227909; called by muse, mutect2
- SLC6A17 | c.375C>T p.R125= | Silent (SNP) | VAF 21/532 reads (4%) | called by muse, mutect2
- SLITRK1 | c.1371C>T p.N457= | Silent (SNP) | VAF 19/499 reads (4%) | catalogued as rs1032347594, COSV65675285; called by muse, mutect2
- SLX4 | c.4905G>A p.K1635= | Silent (SNP) | VAF 22/631 reads (3%) | called by muse, mutect2
- SOBP | c.1695C>T p.N565= | Silent (SNP) | VAF 17/578 reads (3%) | called by muse, mutect2
- SORL1 | c.1497G>A p.S499= | Silent (SNP) | VAF 21/292 reads (7%) | catalogued as rs199858814, COSV99493737; called by muse, mutect2
- SOWAHA | c.1119C>T p.G373= | Silent (SNP) | VAF 26/679 reads (4%) | called by muse, mutect2
- SOX5 | c.729G>A p.Q243= | Silent (SNP) | VAF 26/564 reads (5%) | called by muse, mutect2
- SPEG | c.2928C>T p.D976= | Silent (SNP) | VAF 26/558 reads (5%) | catalogued as rs896686548, COSV104395098; called by muse, mutect2
- ST6GALNAC5 | c.429C>A p.V143= | Silent (SNP) | VAF 23/578 reads (4%) | catalogued as COSV100602887, COSV100603200; called by muse, mutect2
- STRADA | c.693C>T p.H231= (on ENST00000336174 / NM_001363786.1; = p.H194= on NM_153335.6) | Silent (SNP) | VAF 13/377 reads (3%) | catalogued as rs1376949867; called by muse, mutect2
- SUSD2 | c.2460A>G p.A820= | Silent (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- TBC1D30 | c.2403G>A p.P801= (on ENST00000542120; = p.P638= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/638 reads (4%) | catalogued as rs1441789711, COSV99970656; called by muse, mutect2
- TBX18 | c.186C>T p.G62= | Silent (SNP) | VAF 30/652 reads (5%) | called by muse, mutect2
- TECPR1 | c.1242C>T p.T414= | Silent (SNP) | VAF 28/572 reads (5%) | catalogued as rs902211674, COSV101130590; called by muse, mutect2
- TESC | c.6C>T p.G2= | Silent (SNP) | VAF 15/421 reads (4%) | called by muse, mutect2
- TFAP2D | c.489G>A p.L163= | Silent (SNP) | VAF 22/477 reads (5%) | catalogued as COSV50419538; called by muse, mutect2
- TFR2 | c.1938C>T p.Y646= | Silent (SNP) | VAF 24/562 reads (4%) | catalogued as rs1324815806, COSV56153630; called by muse, mutect2
- THSD4 | c.411G>A p.L137= | Silent (SNP) | VAF 25/537 reads (5%) | called by muse, mutect2
- TIE1 | c.1806C>T p.A602= | Silent (SNP) | VAF 28/652 reads (4%) | catalogued as COSV65251488; called by muse, mutect2
- TMEM245 | c.2559G>A p.T853= | Silent (SNP) | VAF 28/362 reads (8%) | catalogued as rs376961293; called by muse, mutect2
- TPM2 | c.663T>C p.Y221= | Silent (SNP) | VAF 18/376 reads (5%) | catalogued as rs1465836003; called by muse, mutect2
- TRAPPC10 | c.1068C>T p.C356= | Silent (SNP) | VAF 14/374 reads (4%) | called by muse, mutect2
- TRIM66 | c.204C>T p.H68= | Silent (SNP) | VAF 19/420 reads (5%) | catalogued as rs1206733950; called by muse, mutect2
- TSC22D1 | c.2172T>C p.P724= | Silent (SNP) | VAF 20/448 reads (4%) | called by muse, mutect2
- TTC34 | c.1116G>A p.A372= | Silent (SNP) | VAF 27/636 reads (4%) | called by muse, mutect2
- TTLL2 | c.1059T>C p.I353= | Silent (SNP) | VAF 19/556 reads (3%) | called by muse, mutect2
- TTN | c.18072A>G p.S6024= (on ENST00000591111; = p.S5097= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/470 reads (4%) | catalogued as rs1256528190; called by muse, mutect2
- TUBA3D | c.981C>T p.D327= | Silent (SNP) | VAF 32/509 reads (6%) | catalogued as rs778776424; called by muse, mutect2
- ULK2 | c.2133A>G p.A711= | Silent (SNP) | VAF 16/421 reads (4%) | called by muse, mutect2
- URB2 | c.1461G>A p.Q487= | Silent (SNP) | VAF 40/702 reads (6%) | catalogued as rs1315529368, COSV51044567; called by muse, mutect2
- UTRN | c.6249T>C p.S2083= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- VCPIP1 | c.168G>A p.A56= | Silent (SNP) | VAF 30/506 reads (6%) | called by muse, mutect2
- VGLL4 | c.750C>G p.L250= | Silent (SNP) | VAF 30/704 reads (4%) | called by muse, mutect2
- VIPAS39 | c.553C>T p.L185= | Silent (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- WDR92 | c.942G>A p.L314= | Silent (SNP) | VAF 18/406 reads (4%) | called by muse, mutect2
- WNT3 | c.366C>T p.G122= | Silent (SNP) | VAF 26/684 reads (4%) | called by muse, mutect2
- YJU2 | c.951C>T p.D317= | Silent (SNP) | VAF 29/345 reads (8%) | called by muse, mutect2
- ZNF316 | c.1182G>A p.T394= | Silent (SNP) | VAF 24/640 reads (4%) | catalogued as rs1022770828; called by muse, mutect2
- ZNF541 | c.939G>A p.S313= | Silent (SNP) | VAF 35/726 reads (5%) | catalogued as COSV54542922; called by muse, mutect2
- ZNF628 | c.1566G>A p.S522= | Silent (SNP) | VAF 19/612 reads (3%) | called by muse, mutect2
- ZNF71 | c.504C>T p.I168= | Silent (SNP) | VAF 18/608 reads (3%) | called by muse, mutect2
- ZXDB | c.717C>T p.P239= | Silent (SNP) | VAF 36/375 reads (10%) | catalogued as rs1234691475; called by muse, mutect2, varscan2
- ANKS6 | c.*724C>T | 3'UTR (SNP) | VAF 19/271 reads (7%) | catalogued as rs1219028240; called by muse, mutect2
- CDK16 | c.-6-363G>A | Intron (SNP) | VAF 21/340 reads (6%) | called by muse, mutect2
- CHCHD4 | c.22+2682C>A | Intron (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
- CYBA | c.369+764T>C | Intron (SNP) | VAF 16/374 reads (4%) | called by muse, mutect2
- G3BP1 | chr5:151770433 C>A | 5'Flank (SNP) | VAF 14/448 reads (3%) | called by muse, mutect2
- IGLV11-55 | c.-1T>C | 5'UTR (SNP) | VAF 13/254 reads (5%) | called by muse, mutect2
- IQCF6 | chr3:51779217 G>A | 5'Flank (SNP) | VAF 23/456 reads (5%) | catalogued as rs961345362; called by muse, mutect2
- KLK11 | c.294-22A>G | Intron (SNP) | VAF 22/410 reads (5%) | called by muse, mutect2
- MFAP4 | c.6+40A>G | Intron (SNP) | VAF 20/558 reads (4%) | called by muse, mutect2
- NDUFV3 | c.170-4901A>C | Intron (SNP) | VAF 24/624 reads (4%) | called by muse, mutect2
- PKLR | c.100+409A>G | Intron (SNP) | VAF 32/555 reads (6%) | called by muse, mutect2
- SH2D3C | c.516-5285A>G | Intron (SNP) | VAF 23/472 reads (5%) | called by muse, mutect2
- SLC9A3 | c.*129C>T | 3'UTR (SNP) | VAF 18/438 reads (4%) | called by muse, mutect2
